Somatic mutation profile of tumor specimen TCGA-BC-A3KF-01A (aliquot TCGA-BC-A3KF-01A-11D-A20W-10) from TCGA case TCGA-BC-A3KF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.6 years (24,328 days).
Specimen TCGA-BC-A3KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 618a1eaa-3bf5-4539-8a95-477b3abb06d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A3KF-10A (Blood Derived Normal), aliquot TCGA-BC-A3KF-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29e019a8-8785-4074-82a8-fa7bed7d1162

The open-access MAF lists 96 somatic variants for this specimen: 70 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 24, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.2236G>C p.G746R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55777152; called by muse, mutect2, varscan2
- AP2A2 | c.1438A>T p.K480* | Nonsense Mutation (SNP) | VAF 60/143 reads (42%) | catalogued as COSV59958761; called by muse, mutect2, varscan2
- AQR | c.992A>T p.Y331F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104381149, COSV50030573; called by muse, mutect2, varscan2
- ATRX | c.5567-1G>A p.X1856_splice | Splice Site (SNP) | VAF 45/97 reads (46%) | catalogued as COSV64873437; called by muse, mutect2, varscan2
- CCDC3 | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV66558895; called by muse, mutect2, varscan2
- CCIN | c.308A>T p.E103V | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV58724264; called by muse, mutect2, varscan2
- CNST | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63620064; called by muse, mutect2, varscan2
- COL11A1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.578); catalogued as COSV62176174; called by muse, mutect2, varscan2
- COL5A3 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53407928; called by muse, mutect2, varscan2
- DAPK2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773075712, COSV56044337; called by muse, mutect2, varscan2
- EDC4 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as COSV59302219; called by muse, mutect2, varscan2
- EPPK1 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV73260954; called by muse, mutect2, varscan2
- GHDC | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as rs1252159909, COSV100054528, COSV56987155; called by muse, mutect2, varscan2
- GLI2 | c.4469C>A p.A1490D (on ENST00000361492 / NM_001374353.1; = p.A1507D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV58037204; called by muse, mutect2, varscan2
- GRIK3 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66136978; called by muse, mutect2, varscan2
- GSTP1 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66992309; called by muse, mutect2, varscan2
- GUCY2C | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53788081; called by muse, mutect2, varscan2
- HCN1 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57499178; called by muse, mutect2, varscan2
- HIPK3 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57561492; called by muse, mutect2, varscan2
- HMGCR | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.605); catalogued as COSV55314905; called by muse, mutect2, varscan2
- HMX2 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474415838, COSV60592507; called by muse, mutect2, varscan2
- HSPA1L | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV65148782; called by muse, mutect2, varscan2
- IGLV3-9 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs374969705; called by muse, mutect2, varscan2
- IL12A | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.438); catalogued as COSV59758901; called by muse, mutect2, varscan2
- IL34 | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55380275; called by muse, mutect2, varscan2
- KCNK9 | c.577T>C p.C193R | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57279397; called by muse, mutect2, varscan2
- KCNT2 | c.290G>C p.W97S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54069705, COSV99650643; called by muse, mutect2, varscan2
- KIF27 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763998301, COSV52826132; called by muse, mutect2, varscan2
- KRTAP5-10 | c.454T>G p.S152A | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV64794327; called by muse, mutect2, varscan2
- KSR2 | c.2323G>C p.G775R | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56668578; called by muse, mutect2, varscan2
- LCN2 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV52979850; called by muse, mutect2, varscan2
- LMCD1 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.686); catalogued as rs1162178766, COSV50087616; called by muse, mutect2, varscan2
- MYH7B | c.1370A>T p.K457M | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53417563; called by muse, mutect2, varscan2
- NEFL | c.1400A>T p.K467M | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55336549; called by muse, mutect2, varscan2
- NMI | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54637724; called by muse, mutect2, varscan2
- OR5L1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1430699573, COSV100450146; called by muse, mutect2, varscan2
- OR5L1 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100450148, COSV61735664; called by muse, mutect2, varscan2
- PCDH11X | c.1871T>A p.V624D | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100013499; called by muse, mutect2, varscan2
- PCDH9 | c.3470C>T p.P1157L (on ENST00000377865 / NM_203487.3; = p.P1123L on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60535813; called by muse, mutect2, varscan2
- PCNT | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs578233518, COSV64026272; called by muse, mutect2, varscan2
- PKHD1L1 | c.5773A>G p.R1925G | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV65739683; called by muse, mutect2, varscan2
- PRR12 | c.916A>T p.S306C (on ENST00000615927; = p.S1127C on NM_020719.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69816915; called by muse, mutect2, varscan2
- PSD4 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV55525253; called by muse, mutect2, varscan2
- PTPRA | c.1639A>T p.N547Y | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV53779542; called by muse, mutect2, varscan2
- RAVER2 | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV53805561; called by muse, mutect2, varscan2
- RGS7 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58534432, COSV58536758; called by muse, mutect2, varscan2
- RIPK2 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV55131956; called by muse, mutect2, varscan2
- RLIM | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60325719; called by muse, mutect2, varscan2
- RNF213 | c.11386A>G p.R3796G | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs144458310; called by muse, mutect2, varscan2
- RTL6 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as rs374819770; called by muse, mutect2, varscan2
- RTN4 | c.1054A>G p.K352E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV58265758, COSV58267465; called by muse, mutect2, varscan2
- SARDH | c.1236A>G p.A412= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as COSV64103900; called by muse, mutect2, varscan2
- SMTN | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.762); catalogued as COSV60776324; called by muse, mutect2, varscan2
- SOX9 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV55422986; called by muse, mutect2, varscan2
- STAG1 | c.2588A>G p.H863R | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52604471; called by muse, mutect2, varscan2
- STAT3 | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52885183; called by muse, mutect2, varscan2
- TCTN2 | c.462A>T p.S154= | Splice Region (SNP) | VAF 110/199 reads (55%) | catalogued as COSV57631968; called by muse, mutect2, varscan2
- TIGD5 | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV100364124; called by muse, mutect2
- TM7SF3 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58001719; called by muse, mutect2, varscan2
- TMEM150B | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV58593355; called by muse, mutect2, varscan2
- TNRC18 | c.6800G>C p.G2267A | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60306727; called by muse, mutect2, varscan2
- TRERF1 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61668637; called by muse, mutect2, varscan2
- TRIM28 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV53399254; called by muse, mutect2, varscan2
- TTN | c.26191T>A p.F8731I (on ENST00000591111; = p.F7804I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | PolyPhen benign (0.011); catalogued as COSV59943250; called by muse, mutect2, varscan2
- UBE2L3 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV60536384; called by muse, mutect2, varscan2
- ZIC1 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51551824, COSV51558768; called by muse, mutect2, varscan2
- HNF4G | c.51_57dup p.T20Qfs*13 (on ENST00000354370 / NM_001330561.2; = p.T67Qfs*13 on NM_004133.5) | Frame Shift Ins (INS) | VAF 22/116 reads (19%) | called by mutect2, varscan2
- INPP5A | c.539del p.L180Wfs*2 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- SLITRK6 | c.1453del p.T485Lfs*3 | Frame Shift Del (DEL) | VAF 50/76 reads (66%) | called by mutect2, pindel, varscan2
- TSC2 | c.4953_4972del p.N1651Kfs*48 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- CADPS | c.4014G>A p.Q1338= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV51871779; called by muse, mutect2, varscan2
- CCDC122 | c.390A>G p.A130= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as COSV55708941; called by muse, mutect2, varscan2
- DHX37 | c.1560A>T p.S520= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as COSV58132876; called by muse, mutect2, varscan2
- FANCM | c.1200A>G p.K400= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs905295349, COSV57498474; ClinVar: likely benign; called by muse, mutect2, varscan2
- HIPK1 | c.1818T>C p.D606= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as COSV61246703; called by muse, mutect2, varscan2
- IGKV2-24 | c.102C>T p.T34= | Silent (SNP) | VAF 121/279 reads (43%) | catalogued as rs755369433; called by muse, mutect2, varscan2
- KCNB2 | c.1497G>A p.L499= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1199682051, COSV73049392; called by muse, mutect2, varscan2
- MROH1 | c.1050A>G p.L350= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs144186714, COSV58189547; called by muse, mutect2, varscan2
- MTX1 | c.534T>C p.Y178= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV57426083; called by muse, mutect2, varscan2
- OPRPN | c.444C>T p.T148= | Silent (SNP) | VAF 86/127 reads (68%) | catalogued as rs767152161, COSV68192648; called by muse, mutect2, varscan2
- OTOGL | c.4008A>T p.T1336= (on ENST00000547103; = p.T1327= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV72006087; called by muse, mutect2, varscan2
- PSMC4 | c.876G>A p.L292= | Silent (SNP) | VAF 99/240 reads (41%) | catalogued as COSV50094487; called by muse, mutect2, varscan2
- SCN7A | c.2085C>T p.D695= | Silent (SNP) | VAF 52/75 reads (69%) | catalogued as rs767132512, COSV69269969; called by muse, mutect2, varscan2
- SIGLEC5 | c.1056A>G p.R352= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs533765364, COSV55778248; called by muse, mutect2, varscan2
- SNRK | c.1155G>A p.A385= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs766398727, COSV56066819; called by muse, mutect2, varscan2
- SRRD | c.1019G>A p.*340= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV53225782; called by mutect2, varscan2
- STT3A | c.480A>T p.R160= | Silent (SNP) | VAF 65/87 reads (75%) | catalogued as COSV67064054; called by muse, mutect2, varscan2
- TMEM130 | c.231C>A p.T77= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs1361450492, COSV59558252; called by muse, mutect2, varscan2
- TOP2B | c.1794T>A p.I598= (on ENST00000264331 / NM_001330700.2; = p.I593= on NM_001068.3) | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV51969934; called by muse, mutect2, varscan2
- TRERF1 | c.2103C>A p.P701= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as COSV61668616; called by muse, mutect2, varscan2
- TRPM1 | c.849A>G p.G283= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV56632013; called by muse, mutect2, varscan2
- UBR5 | c.4728G>A p.E1576= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as rs1471225051, COSV55282670; called by muse, mutect2, varscan2
- USP25 | c.408C>T p.S136= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV53480174; called by muse, mutect2
- YY2 | c.660T>A p.P220= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV63410970; called by muse, mutect2, varscan2
- HPD | c.-1C>T | 5'UTR (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100000178; called by muse, mutect2, varscan2
- MSH5 | c.2182-66T>C | Intron (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
